Surgical pathology report (de-identified scan), TCGA case TCGA-ZF-A9RF, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Sheffield, specimen TCGA-ZF-A9RF-01A (Primary Tumor).

SPECIMEN

Bladder tumour

CLINICAL DETAILS

New bladder tumour - TURT.

MACROSCOPY

8g of firm tissue chippings.

MICROSCOPY

Grade 3 Poorly differentiated with large foci of necrosis

Growth pattern Predominantly solid

Type Transitional cell carcinoma

Muscularis propria present Yes

Stromal invasion Invasion of muscularis propria (pT2)

Vascular channel invasion Not identified

Background urothelium Flat urothelium is present which is not dysplastic

Summary Transitional cell carcinoma G3pT2

Pathologists -

CHF ICD-O-3
Carcinoma, urothelial NOS 8120/3
path
Carcinoma, transitional cell NOS 8120/3
Site Bladder NOS C67.9
JY 5/2/14

Source: NCI Genomic Data Commons file 69d71e0b-ec64-413d-aa65-fdfb312fb9ff (TCGA-ZF-A9RF.CBA9E3B1-AD28-4E0B-B851-D70ACAED921A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).